Gene-level copy-number profile of tumor specimen TCGA-YJ-A8SW-01A from TCGA case TCGA-YJ-A8SW, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Prostate gland.
Specimen TCGA-YJ-A8SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.1013996a-5544-46d7-8d5f-baba022aa9bf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YJ-A8SW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 848 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff50c5f3-5c9f-4d70-a1b0-ec671c94b17f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,099; copy number 2: 36,256; copy number 3: 14,770; copy number 4: 3,118; copy number 5: 1,018; copy number 6: 260; copy number 7: 91; copy number 8: 55; copy number 9: 107.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YJ-A8SW-01A-11D-A376-01): tumor purity 0.83, ploidy 2.4, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,531 genes in 52 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,383,838–40,594,353, 76 genes, copy number 5 (broad region; genes not listed).
- chr2:98,997,261–100,509,612, 24 genes, copy number 5 (within-gene range 3–5): TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1, AFF3, AC092667.1, LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2.
- chr2:117,023,918–118,222,250, 18 genes, copy number 5: MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1, AC009312.1, DDX18, AC009404.1, HTR5BP, CCDC93, AC009303.1, AC009303.2, AC009303.3, AC009303.4, RN7SL111P, INSIG2, THORLNC.
- chr3:9,292,588–10,940,714, 58 genes, copy number 6 (within-gene range 3–6): AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13, ATP2B2, MIR378B, MIR885, ATP2B2-IT1, ATP2B2-IT2, LINC00606, AC018495.1, SLC6A11.
- chr3:29,054,570–29,391,218, 3 genes, copy number 6: RBMS3-AS3, MESTP4, RPS12P5.
- chr3:41,246,599–44,332,098, 66 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:81,762,706–84,051,419, 9 genes, copy number 6: AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1.
- chr3:86,481,943–87,158,363, 5 genes, copy number 5: LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506.
- chr3:108,380,368–108,725,536, 7 genes, copy number 6 (within-gene range 4–6): MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1.
- chr3:133,746,040–137,796,678, 57 genes, copy number 6: TF, AC080128.1, SRPRB, AC080128.2, RAB6B, C3orf36, SLCO2A1, LINC02000, RYK, HMGB3P14, LINC02004, AC010207.1, RPL39P5, AMOTL2, MIR6827, HMGN1P9, HMGB3P13, MIR4788, ANAPC13, CEP63, AC026117.1, EPHB1, KY, AC016931.1, RNU6-1174P, RNA5SP141, AC092969.1, AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1.
- chr3:153,607,377–154,861,017, 16 genes, copy number 5: Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2.
- chr3:169,003,022–172,831,229, 82 genes, copy number 5 (broad region; genes not listed).
- chr3:175,234,861–179,627,647, 65 genes, copy number 5–7 (broad region; genes not listed).
- chr3:185,162,871–186,922,753, 55 genes, copy number 5: EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, AC099661.1, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG, LINC02020, LINC02052, LINC02051, CRYGS, TBCCD1, DNAJB11, AC068631.1, AC068631.2, AC068631.3, AHSG, Metazoa_SRP, FETUB, HRG, AC109780.1, AC109780.2, KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1.
- chr4:169,572,328–170,283,723, 16 genes, copy number 5: AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612.
- chr5:92,082,597–94,176,029, 23 genes, copy number 5 (within-gene range 2–5): AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, AC026408.1, POLD2P1, NR2F1-AS1, NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1.
- chr5:113,323,028–113,595,285, 4 genes, copy number 5 (within-gene range 3–5): AC079465.1, TSSK1B, RNU4ATAC13P, YTHDC2.
- chr5:118,758,211–119,681,080, 23 genes, copy number 6: RNU7-34P, AC093206.1, DTWD2, PTMAP2, MIR1244-2, AC008629.1, RNU6-373P, AC008629.2, AC008629.3, DMXL1, AC118465.1, LAMTOR3P2, RNU6-701P, MIR5706, TNFAIP8, RN7SL174P, RNA5SP190, HSD17B4, AC010409.1, FABP5P6, FAM170A, TUBAP15, AC008550.1.
- chr5:154,857,553–157,142,869, 21 genes, copy number 5–6 (within-gene range 4–6): CNOT8, GEMIN5, MRPL22, AC008410.1, KIF4B, AC010476.2, AC010476.1, AC010591.1, AC008725.1, RNA5SP199, SGCD, AC011351.1, AC027308.1, AC025434.1, RNU6-556P, PPP1R2B, TIMD4, APOOP1, HAVCR1, HAVCR2, AC011377.1.
- chr6:45,328,157–46,207,386, 9 genes, copy number 5: RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9.
- chr6:145,735,570–145,964,423, 8 genes, copy number 5: AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT, SHPRH.
- chr7:11,180,902–12,440,404, 8 genes, copy number 5: AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3.
- chr7:13,854,355–20,777,038, 81 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:24,132,705–25,949,986, 30 genes, copy number 5: RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A.
- chr7:32,427,901–34,299,012, 37 genes, copy number 6: AC018637.1, AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9, BBS9, AC074338.1, RNA5SP229, AC007312.1, AC006195.1, AC008080.1, AC008080.2, AC008080.4, AC008080.3, BMPER, AC007350.1, AC009262.1, RNU6-438P.
- chr7:35,614,650–36,453,791, 27 genes, copy number 5 (within-gene range 3–5): AC018647.3, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4, AC083864.5, AC083864.2, AC083864.4, AC083864.1, AC083864.3, MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN.
- chr7:65,463,071–67,302,419, 63 genes, copy number 5 (broad region; genes not listed).
- chr7:94,695,027–94,834,447, 6 genes, copy number 7: RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1.
- chr7:97,598,933–100,041,689, 81 genes, copy number 5 (broad region; genes not listed).
- chr8:73,241,329–74,518,007, 34 genes, copy number 6: C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA.
- chr8:80,204,606–84,164,564, 67 genes, copy number 7–8 (broad region; genes not listed).
- chr8:93,646,066–94,707,466, 33 genes, copy number 5 (within-gene range 4–5): ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP.
- chr8:123,984,138–128,564,679, 80 genes, copy number 5–9 (broad region; genes not listed).
- chr8:135,457,456–139,704,109, 21 genes, copy number 5 (within-gene range 4–5): KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9.
- chr9:12,764,761–13,323,450, 9 genes, copy number 5: RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1.
- chr9:35,161,992–35,958,154, 46 genes, copy number 5 (within-gene range 4–5): UNC13B, AL160274.1, ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2.
- chr11:65,367,438–68,942,852, 205 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr16:27,066,707–27,364,778, 10 genes, copy number 5: C16orf82, AC092725.1, EEF1A1P38, LINC02129, KDM8, AC109449.1, NSMCE1, NSMCE1-DT, AC106739.1, IL4R.
- chr17:77,877,330–78,142,968, 8 genes, copy number 5: LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P, TMC6, TMC8.
- chr18:58,371,566–58,757,842, 20 genes, copy number 5: AC090236.2, AC090236.1, AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2.

Autosomal genes at a single copy (total copy number 1): 1,920. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
